TCGA case TCGA-YU-A94N — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/163aa9b8-e1eb-440b-b0ab-9c75dd8c2824

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 23 years; Year of birth: 1988; Vital status: Alive.

Diagnoses (2)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 23.0 years (8,416 days); Year of diagnosis: 2011; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical N: N3; AJCC clinical M: M1b; AJCC clinical stage: Stage IIIC; AJCC pathologic T: T2; AJCC pathologic stage: Stage IIIC; IGCCCG stage: Poor Prognosis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,575 days (4.3 years); Ajcc serum tumor markers: S3; Sites of involvement: Rete Testis / Tunica Albuginea.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin; Treatment intent type: Adjuvant; Days to treatment start: 3 days; Days to treatment end: 91 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Ifosfamide + Paclitaxel; Treatment intent type: Adjuvant; Regimen or line of therapy: TIP; Days to treatment start: 483 days (1.3 years); Days to treatment end: 549 days (1.5 years); Treatment outcome: Partial Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Seminoma, NOS), site: Intra-abdominal lymph nodes. Age at diagnosis: 24.1 years (8,793 days); Days to diagnosis: 377 days (1.0 years); Prior treatment: Yes.

Follow-up (6 entries)
- Day 377 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 377 days (1.0 years).
- Days to follow up: 1,197 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,323 days (3.6 years); Disease response: Tumor Free.
- Days to follow up: 1,392 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,575 days (4.3 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 1: Lactate Dehydrogenase 1645; Alpha Fetoprotein 13597; Human Chorionic Gonadotropin 58.3.
- Day 7: Lactate Dehydrogenase 1891; Alpha Fetoprotein 14103; Human Chorionic Gonadotropin 78.6.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YU-A94N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 150 mg.
  Slide TCGA-YU-A94N-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-YU-A94N-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YU-A94N-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
